Somatic mutation profile of tumor specimen C3L-05302-01 (aliquot CPT0281990006) from CPTAC case C3L-05302, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 72.7 years (26,559 days).
Specimen C3L-05302-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8b1ee0f-d081-4cbf-a794-b61f35466ef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05302-31 (Blood Derived Normal), aliquot CPT0282150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b9aef53-af81-44f4-a10a-35f806396956

The open-access MAF lists 100 somatic variants for this specimen: 72 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Nonsense Mutation 7, Intron 3, Splice Site 3, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 223/488 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM8 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 157/365 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs765395197; called by muse, mutect2, varscan2
- ALS2CL | c.2727G>A p.M909I | Missense Mutation (SNP) | VAF 205/470 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs146989129; called by muse, mutect2, varscan2
- ATXN2L | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs1049301799, COSV104395217; called by muse, mutect2, varscan2
- CATSPERG | c.3113G>A p.R1038K | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV53048009; called by muse, mutect2, varscan2
- CDCP1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 182/409 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as rs141965879; called by muse, mutect2, varscan2
- CFTR | c.2881A>T p.M961L | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV50132900; called by muse, mutect2, varscan2
- CLCA2 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 202/524 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV100991349; called by muse, mutect2, varscan2
- COL14A1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 360/407 reads (88%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV52853350; called by muse, mutect2, varscan2
- CWH43 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56944020, COSV99894069; called by muse, mutect2, varscan2
- DAZAP1 | c.774del p.P260Hfs*75 | Frame Shift Del (DEL) | VAF 55/199 reads (28%) | catalogued as rs1388829468; called by mutect2, pindel, varscan2
- DSCAM | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 279/606 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68023134; called by muse, mutect2, varscan2
- ELOA2 | c.1812G>A p.W604* | Nonsense Mutation (SNP) | VAF 183/427 reads (43%) | catalogued as rs775193976; called by muse, mutect2, varscan2
- GSPT2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 233/265 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV61213930; called by muse, mutect2, varscan2
- ITPRID1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs1160950205; called by muse, mutect2, varscan2
- KRT36 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 133/284 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752593807, COSV60204210; called by muse, mutect2, varscan2
- LRIT1 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 217/529 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs772075587, COSV64512250; called by muse, mutect2, varscan2
- MUC15 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs779223477, COSV55553970; called by muse, mutect2, varscan2
- MYH1 | c.2113G>A p.G705S | Missense Mutation (SNP) | VAF 235/544 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1020787646; called by muse, mutect2, varscan2
- NYAP2 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 286/638 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs367790714, COSV99797161; called by muse, mutect2, varscan2
- OR2J2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 237/823 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs761974714; called by muse, mutect2, varscan2
- OR4K5 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs868852438; called by muse, mutect2, varscan2
- OR51G1 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58968824; called by muse, mutect2, varscan2
- PCDH15 | c.3161T>A p.M1054K | Missense Mutation (SNP) | VAF 150/358 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV57308406; called by muse, mutect2, varscan2
- PIEZO1 | c.6056G>A p.R2019H | Missense Mutation (SNP) | VAF 238/538 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747845025; called by muse, mutect2, varscan2
- PRPF6 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 165/339 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53870101; called by muse, mutect2, varscan2
- PTGES | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 178/432 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1286156301; called by muse, mutect2, varscan2
- RGS10 | c.313C>T p.R105W (on ENST00000369101; = p.R99W on NM_002925.3) | Missense Mutation (SNP) | VAF 21/582 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as rs1237385264; called by muse, mutect2
- SCN10A | c.3836C>T p.P1279L | Missense Mutation (SNP) | VAF 187/450 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101479288; called by muse, mutect2, varscan2
- SCN9A | c.5011A>T p.K1671* (on ENST00000303354; = p.K1660* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 211/477 reads (44%) | catalogued as rs1553473225; called by muse, mutect2, varscan2
- SEMA3G | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 159/387 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as rs752179434, COSV51595664; called by muse, mutect2, varscan2
- SLCO1A2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56598935, COSV56605393; called by muse, mutect2, varscan2
- SNCAIP | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 164/205 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145687025; called by muse, mutect2, varscan2
- SQOR | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 207/456 reads (45%) | catalogued as rs1453700860, COSV52941825; called by muse, mutect2, varscan2
- SUSD2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 204/460 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238378434, COSV64205207; called by muse, mutect2, varscan2
- TP63 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 225/502 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53201419; called by muse, mutect2, varscan2
- ZSCAN4 | c.1111A>C p.S371R | Missense Mutation (SNP) | VAF 171/373 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs75618108; called by muse, mutect2, varscan2
- ABCC8 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 199/486 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ABHD5 | c.169A>C p.I57L | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DRICH1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 136/380 reads (36%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 243/501 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EIF2B4 | c.994G>A p.V332M (on ENST00000347454 / NM_001034116.2; = p.V331M on NM_015636.3) | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EOMES | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 108/283 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- FAM114A1 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 150/359 reads (42%) | called by muse, mutect2, varscan2
- FBP1 | c.679T>A p.Y227N | Missense Mutation (SNP) | VAF 170/393 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMAP4 | c.378C>A p.Y126* | Nonsense Mutation (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- GRIK4 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 142/338 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3-15 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 261/871 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- IL31RA | c.2051A>T p.K684I | Missense Mutation (SNP) | VAF 214/318 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ITGB6 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IVL | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 534/916 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LARP4B | c.1125+1G>T p.X375_splice | Splice Site (SNP) | VAF 126/281 reads (45%) | called by muse, mutect2, varscan2
- LRRC2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 162/413 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MALRD1 | c.5935C>T p.L1979F | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MSH6 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MYOM3 | c.1717T>G p.F573V | Missense Mutation (SNP) | VAF 242/597 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NEB | c.17697+1G>T p.X5899_splice | Splice Site (SNP) | VAF 129/309 reads (42%) | called by muse, mutect2, varscan2
- NLRP3 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 206/638 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PCF11 | c.1969_1970insTTTAA p.T657Ifs*2 | Frame Shift Ins (INS) | VAF 91/287 reads (32%) | called by mutect2, pindel, varscan2
- PCGF2 | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 158/386 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PREX1 | c.4607T>C p.I1536T | Missense Mutation (SNP) | VAF 162/369 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RGSL1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 440/729 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3KBP1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 170/192 reads (89%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TOX4 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 222/519 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TTN | c.30397+1G>A p.X10133_splice (on ENST00000591111; = p.X9206_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 65/193 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.20588G>A p.G6863E (on ENST00000591111; = p.G5936E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 266/602 reads (44%) | PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- UBOX5 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 182/230 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- URB1 | c.4088C>T p.S1363F | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- VLDLR | c.1763G>A p.G588E | Missense Mutation (SNP) | VAF 181/412 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WDR49 | c.790C>T p.Q264* (on ENST00000308378 / NM_001366158.1; = p.Q605* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 91/221 reads (41%) | called by muse, mutect2, varscan2
- ZC4H2 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 195/233 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CACNA1E | c.1746A>C p.I582= | Silent (SNP) | VAF 205/334 reads (61%) | called by muse, mutect2, varscan2
- CCDC185 | c.1548G>A p.Q516= | Silent (SNP) | VAF 235/766 reads (31%) | catalogued as rs751177174; called by muse, mutect2, varscan2
- CD33 | c.1032C>T p.N344= | Silent (SNP) | VAF 201/473 reads (42%) | catalogued as COSV51801332; called by muse, mutect2, varscan2
- DNAH9 | c.4752C>T p.C1584= | Silent (SNP) | VAF 142/311 reads (46%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.9012C>T p.F3004= | Silent (SNP) | VAF 169/373 reads (45%) | called by muse, mutect2, varscan2
- FKBPL | c.156C>T p.S52= | Silent (SNP) | VAF 308/1110 reads (28%) | called by muse, mutect2, varscan2
- GRIN2A | c.1962C>T p.I654= | Silent (SNP) | VAF 204/461 reads (44%) | catalogued as COSV58042055, COSV58055470; called by muse, mutect2, varscan2
- KCNMB1 | c.15G>A p.L5= | Silent (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2
- MYH4 | c.1239C>T p.F413= | Silent (SNP) | VAF 113/278 reads (41%) | catalogued as rs370061303; called by muse, mutect2, varscan2
- MYH8 | c.5220C>T p.L1740= | Silent (SNP) | VAF 122/320 reads (38%) | catalogued as COSV67963680; called by muse, mutect2, varscan2
- MYOM3 | c.1716C>T p.V572= | Silent (SNP) | VAF 243/605 reads (40%) | called by muse, mutect2
- OR10A4 | c.51C>T p.F17= | Silent (SNP) | VAF 187/448 reads (42%) | called by muse, mutect2, varscan2
- OR11H12 | c.450C>T p.I150= | Silent (SNP) | VAF 174/1766 reads (10%) | catalogued as COSV73569136; called by muse, mutect2, varscan2
- OR11H4 | c.846G>A p.K282= | Silent (SNP) | VAF 187/364 reads (51%) | called by muse, mutect2, varscan2
- OR13A1 | c.522G>C p.T174= | Silent (SNP) | VAF 297/716 reads (41%) | catalogued as rs372588526; called by muse, mutect2, varscan2
- OR13C3 | c.543C>T p.S181= | Silent (SNP) | VAF 226/489 reads (46%) | catalogued as rs779802213, COSV66165902; called by muse, mutect2, varscan2
- OR14I1 | c.513G>A p.V171= | Silent (SNP) | VAF 404/728 reads (55%) | catalogued as rs563232017, COSV61199577; called by muse, mutect2
- OR4A8 | c.372C>T p.T124= | Silent (SNP) | VAF 165/385 reads (43%) | called by muse, mutect2, varscan2
- RERE | c.2166G>A p.E722= | Silent (SNP) | VAF 279/671 reads (42%) | called by muse, mutect2, varscan2
- SIVA1 | c.171G>A p.V57= | Silent (SNP) | VAF 264/618 reads (43%) | catalogued as rs1345453879; called by muse, mutect2
- VAV1 | c.813C>T p.I271= | Silent (SNP) | VAF 200/409 reads (49%) | catalogued as rs753340238; called by muse, mutect2, varscan2
- VLDLR | c.1887G>A p.L629= | Silent (SNP) | VAF 204/482 reads (42%) | catalogued as rs775717014; called by muse, varscan2
- VLDLR | c.2004T>C p.Y668= | Silent (SNP) | VAF 174/463 reads (38%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149723 G>A | 5'Flank (SNP) | VAF 142/350 reads (41%) | catalogued as rs866219581; called by muse, mutect2, varscan2
- CAV1 | c.*516A>G | 3'UTR (SNP) | VAF 174/404 reads (43%) | catalogued as rs1022702043; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1889A>G | Intron (SNP) | VAF 265/882 reads (30%) | catalogued as rs1449210460; called by muse, mutect2, varscan2
- TASOR | c.4301-246G>T | Intron (SNP) | VAF 125/305 reads (41%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.374+335C>T | Intron (SNP) | VAF 135/334 reads (40%) | catalogued as rs1353026259; called by muse, mutect2, varscan2
